Somatic mutation profile of tumor specimen TCGA-HC-8213-01A (aliquot TCGA-HC-8213-01A-11D-A29Q-08) from TCGA case TCGA-HC-8213, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 48.4 years (17,673 days).
Specimen TCGA-HC-8213-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e3a9106-21ac-423c-a46c-ff96a8f0527f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-8213-10A (Blood Derived Normal), aliquot TCGA-HC-8213-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04830c2f-834f-48c8-9713-38a3f3979854

The open-access MAF lists 17 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 14, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY1 | c.2944G>T p.G982C | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52042331; called by muse, mutect2
- CACNA1E | c.5258G>A p.R1753Q | Missense Mutation (SNP) | VAF 81/190 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs371470806; called by muse, mutect2, varscan2
- CD300LB | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 98/244 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.86); catalogued as rs752893026, COSV58726179; called by muse, varscan2
- CDH12 | c.554C>G p.T185R | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV66446901; called by muse, mutect2, varscan2
- CGN | c.3368G>A p.R1123Q | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs555924887, COSV54973627; called by muse, mutect2, varscan2
- EPHA3 | c.2921C>T p.T974M | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs780470195, COSV60693883, COSV60732575; called by muse, mutect2, varscan2
- KBTBD6 | c.1187A>T p.Y396F | Missense Mutation (SNP) | VAF 80/188 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as COSV65271988; called by muse, mutect2, varscan2
- KCNA3 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63902574; called by muse, mutect2, varscan2
- MUC6 | c.2266C>T p.R756W | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs994296367, COSV70149909; called by muse, mutect2
- SORCS2 | c.2572G>A p.A858T | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as COSV61183002; called by mutect2, varscan2
- SYNJ2 | c.3677T>A p.L1226H | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.711); catalogued as COSV62900768; called by muse, mutect2, varscan2
- TFDP3 | c.896G>A p.G299D | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV59538461; called by muse, mutect2
- TMEM177 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as rs1245015841, COSV55609613; called by muse, mutect2
- ZSCAN10 | c.2140C>T p.R714C (on ENST00000252463; = p.R769C on NM_032805.3) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52970826; called by muse, mutect2, varscan2
- CLUH | c.338del p.G113Afs*47 (on ENST00000435359; = p.G151Afs*47 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 7/19 reads (37%) | called by mutect2, pindel, varscan2
- CADPS | c.1944G>C p.L648= | Silent (SNP) | VAF 40/114 reads (35%) | catalogued as COSV51901923; called by muse, mutect2, varscan2
- CFH | c.3012G>A p.K1004= | Silent (SNP) | VAF 5/99 reads (5%) | catalogued as COSV66408707; called by muse, mutect2
